Somatic mutation profile of tumor specimen TCGA-06-0157-01A (aliquot TCGA-06-0157-01A-01D-1491-08) from TCGA case TCGA-06-0157, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,128 days).
Specimen TCGA-06-0157-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4048e8ff-3346-424d-b094-12a7471a8b52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0157-10A (Blood Derived Normal), aliquot TCGA-06-0157-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2242451e-9382-43ad-916d-1ed9690e4130

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 2301/2480 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AQP7 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53010691; called by muse, mutect2, varscan2
- C20orf27 | c.398G>A p.R133H (on ENST00000379772 / NM_001258429.2; = p.R158H on NM_001039140.3) | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs374709259; called by muse, mutect2, varscan2
- DNAH9 | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773854763, COSV52342004; called by muse, mutect2, varscan2
- FFAR1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199506594, COSV50050607; called by muse, mutect2
- GATA4 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV58732858; called by muse, mutect2, varscan2
- GPR101 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs887953877, COSV53237364; called by muse, mutect2, varscan2
- HAO1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs373454999, COSV66491862; called by muse, mutect2, varscan2
- HLA-DRB5 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 96/302 reads (32%) | catalogued as rs774817822, COSV66616806; called by muse, varscan2
- HSD11B1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374552497; called by muse, mutect2, varscan2
- HSPA12A | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782128836, COSV65021557; called by muse, mutect2, varscan2
- KCNH5 | c.1475T>A p.L492Q | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59755746; called by muse, mutect2, varscan2
- KCNQ1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs370435862, CM143793, COSV50102993; called by muse, mutect2, varscan2
- NONO | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV52136638; called by muse, mutect2, varscan2
- PCLO | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs771331973, COSV61624146, COSV61682522; called by muse, mutect2, varscan2
- PDE1A | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59518399, COSV59523148; called by muse, mutect2, varscan2
- PTK6 | c.24C>A p.H8Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53916241; called by muse, mutect2, varscan2
- RADIL | c.1526G>A p.W509* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as COSV68200000; called by muse, mutect2, varscan2
- RHBDL1 | c.731G>A p.R244H (on ENST00000219551 / NM_001318733.2; = p.R179H on NM_001278720.2) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs758434424, COSV53483336; called by muse, mutect2, varscan2
- RPS12 | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 42/100 reads (42%) | catalogued as COSV57766815; called by muse, mutect2, varscan2
- RPS6KA3 | c.1142T>A p.L381H | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV65387294; called by muse, mutect2, varscan2
- RYR2 | c.5198C>T p.T1733M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs750668049, COSV63674312; called by muse, mutect2, varscan2
- SLC12A4 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs200235448, COSV57926906; called by muse, mutect2, varscan2
- SLC18A1 | c.931T>A p.F311I | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.277); catalogued as COSV52347368; called by muse, mutect2, varscan2
- SNRNP200 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV60488335; called by muse, mutect2, varscan2
- SNX11 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV63658209; called by muse, mutect2, varscan2
- SPTA1 | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs751271842, COSV63749494, COSV63757490; called by muse, mutect2, varscan2
- SYNDIG1 | c.618+1G>A p.X206_splice | Splice Site (SNP) | VAF 126/267 reads (47%) | catalogued as COSV65233343; called by muse, mutect2, varscan2
- SYP | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV54294597; called by muse, mutect2, varscan2
- SYT2 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66141595; called by muse, mutect2, varscan2
- TARS1 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV54308203; called by muse, mutect2, varscan2
- TBR1 | c.1315A>G p.N439D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV67417521; called by muse, varscan2
- TNRC6C | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs781193694, COSV56942630; called by muse, mutect2, varscan2
- TTN | c.33055C>T p.R11019C (on ENST00000591111; = p.R10092C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | PolyPhen benign (0.172); catalogued as rs763380355, COSV59956834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTS2R | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs751853532, COSV57452667; called by muse, mutect2, varscan2
- VWF | c.5510G>A p.R1837Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs545304154, COSV54615286; called by muse, mutect2, varscan2
- XK | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66119873; called by muse, mutect2, varscan2
- ZFP82 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 209/480 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.688); catalogued as COSV67564947; called by muse, mutect2, varscan2
- DNAJB11 | c.1002del p.A335Rfs*9 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- JAKMIP3 | c.1022del p.N341Tfs*22 | Frame Shift Del (DEL) | VAF 11/17 reads (65%) | called by mutect2, pindel, varscan2
- MRPL13 | c.315dup p.L106Tfs*26 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- PTEN | c.227_228del p.Y76* | Frame Shift Del (DEL) | VAF 23/53 reads (43%) | called by mutect2, pindel, varscan2
- AWAT1 | c.249C>A p.P83= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV65738339; called by muse, mutect2, varscan2
- CDH15 | c.2193C>T p.Y731= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs780699760, COSV57022907; called by muse, mutect2, varscan2
- COL4A1 | c.135G>A p.K45= | Silent (SNP) | VAF 186/527 reads (35%) | catalogued as COSV65423182; called by muse, mutect2, varscan2
- EGFL6 | c.1158G>A p.A386= | Silent (SNP) | VAF 88/183 reads (48%) | catalogued as rs776641020, COSV63633297; called by muse, mutect2, varscan2
- ERVW-1 | c.885C>A p.P295= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- IRX1 | c.1413G>A p.P471= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs766443357, COSV57358619; called by muse, mutect2, varscan2
- KRTAP13-2 | c.243C>T p.Y81= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs756813722, COSV101299623, COSV67761924; called by muse, mutect2, varscan2
- LAMA1 | c.2529C>T p.G843= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs774533568, COSV67534182; called by muse, mutect2, varscan2
- MUC16 | c.23787T>A p.S7929= | Silent (SNP) | VAF 71/171 reads (42%) | catalogued as COSV67454863; called by muse, mutect2, varscan2
- SERPINC1 | c.1119C>T p.V373= | Silent (SNP) | VAF 70/169 reads (41%) | catalogued as rs1271197978, COSV62929070; called by muse, mutect2, varscan2
- TAS2R13 | c.411C>T p.T137= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV66831537, COSV66831754; called by muse, mutect2, varscan2
- UGT2B4 | c.477G>C p.L159= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs745701769, COSV59316075; called by muse, mutect2, varscan2
- ZNF419 | c.1059C>T p.S353= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV55658487; called by muse, mutect2, varscan2
